Somatic mutation profile of tumor specimen TCGA-CJ-6027-01A (aliquot TCGA-CJ-6027-01A-11D-1669-08) from TCGA case TCGA-CJ-6027, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G4; Age at diagnosis: 77.6 years (28,359 days).
Specimen TCGA-CJ-6027-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b0a3b0e5-c989-4690-99ca-b897e970ce35.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CJ-6027-11A (Solid Tissue Normal), aliquot TCGA-CJ-6027-11A-01D-1669-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a140a0e4-3d93-4564-9573-5fa4bd74033d

The open-access MAF lists 87 somatic variants for this specimen: 66 protein-altering or splice-affecting, 19 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 48, Silent 19, Frame Shift Del 6, Nonsense Mutation 5, Frame Shift Ins 3, Splice Site 2, 5'UTR 1, In Frame Ins 1, In Frame Del 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SCARB2 | c.1270C>T p.R424* | Nonsense Mutation (SNP) | VAF 28/134 reads (21%) | catalogued as rs886041078, CM143649, COSV53667794; ClinVar: pathogenic; called by muse, mutect2, varscan2
- VHL | c.266T>C p.L89P | Missense Mutation (SNP) | VAF 4/23 reads (17%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs5030807, CM941368, COSV56543066, COSV56543312, COSV56543561; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCG8 | c.226A>G p.T76A | Missense Mutation (SNP) | VAF 24/93 reads (26%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as COSV55391152; called by muse, mutect2, varscan2
- AC013489.1 | c.1267C>T p.R423C | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.926); catalogued as rs569976232, COSV51550330; called by muse, mutect2, varscan2
- ACTL9 | c.1120C>T p.P374S | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.897); catalogued as rs1401344237, COSV61004982; called by muse, mutect2, varscan2
- ATP5F1B | c.1074+1G>T p.X358_splice | Splice Site (SNP) | VAF 31/101 reads (31%) | catalogued as COSV56260414; called by muse, mutect2, varscan2
- ATP8B3 | c.91T>A p.S31T | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.757); catalogued as COSV50075311; called by muse, mutect2, varscan2
- ATRX | c.266A>T p.Y89F | Missense Mutation (SNP) | VAF 50/86 reads (58%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV64869299; called by muse, mutect2, varscan2
- B3GAT3 | c.545C>T p.P182L | Missense Mutation (SNP) | VAF 15/178 reads (8%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.714); catalogued as COSV53881580; called by muse, mutect2
- BDKRB2 | c.64G>T p.A22S | Missense Mutation (SNP) | VAF 49/131 reads (37%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.077); catalogued as COSV60013822; called by muse, mutect2, varscan2
- BRPF3 | c.1843G>A p.A615T | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT tolerated (0.25); PolyPhen benign (0.02); catalogued as rs773365971, COSV60206299; called by muse, mutect2, varscan2
- CDC23 | c.251T>C p.M84T | Missense Mutation (SNP) | VAF 34/128 reads (27%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV67508313; called by muse, mutect2, varscan2
- CNTN2 | c.1811T>A p.V604D | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV59348450; called by muse, mutect2, varscan2
- DPY19L1 | c.137G>C p.R46P | Missense Mutation (SNP) | VAF 24/109 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV60581164; called by muse, mutect2, varscan2
- FAM83C | c.1483_1485del p.K495del | In Frame Del (DEL) | VAF 24/98 reads (24%) | catalogued as rs756547646; called by mutect2, pindel, varscan2
- FNIP2 | c.2536G>A p.E846K | Missense Mutation (SNP) | VAF 21/130 reads (16%) | SIFT tolerated (0.57); PolyPhen benign (0.006); catalogued as rs1221214237, COSV52437146; called by muse, mutect2, varscan2
- GPRIN3 | c.716C>A p.T239N | Missense Mutation (SNP) | VAF 23/100 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.014); catalogued as COSV60884163, COSV60884267; called by muse, mutect2, varscan2
- IARS1 | c.1888T>A p.S630T | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65114195; called by muse, mutect2, varscan2
- IL23R | c.1083C>G p.I361M | Missense Mutation (SNP) | VAF 18/117 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.363); catalogued as COSV61373110, COSV61376337; called by muse, mutect2, varscan2
- KHK | c.344+1G>A p.X115_splice | Splice Site (SNP) | VAF 21/81 reads (26%) | catalogued as rs200086908, COSV53153610; called by muse, mutect2, varscan2
- KIAA0586 | c.2052C>G p.F684L (on ENST00000619416 / NM_001244190.2; = p.F623L on NM_014749.5) | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT tolerated (0.7); PolyPhen benign (0.003); catalogued as rs970847752, COSV54171993; called by muse, mutect2, varscan2
- KLF11 | c.281T>C p.L94P | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.035); catalogued as COSV59940098; called by muse, mutect2, varscan2
- LACRT | c.238G>T p.E80* | Nonsense Mutation (SNP) | VAF 47/144 reads (33%) | catalogued as COSV57687788; called by muse, mutect2, varscan2
- LAMC2 | c.161T>A p.L54H | Missense Mutation (SNP) | VAF 114/450 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV51452922; called by muse, mutect2, varscan2
- LMOD1 | c.484C>T p.R162W | Missense Mutation (SNP) | VAF 27/97 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); catalogued as rs756783701, COSV100939245, COSV66171994; called by muse, varscan2
- MORC3 | c.1475G>A p.R492Q | Missense Mutation (SNP) | VAF 49/220 reads (22%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs1274628935, COSV68203530; called by muse, mutect2, varscan2
- MTOR | c.4555G>A p.A1519T | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV63868966; called by muse, mutect2, varscan2
- NEBL | c.1381G>T p.G461* | Nonsense Mutation (SNP) | VAF 80/329 reads (24%) | catalogued as COSV65801666; called by muse, mutect2, varscan2
- NEDD9 | c.425T>C p.I142T | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs111447705; called by muse, mutect2, varscan2
- NR4A3 | c.262G>T p.E88* | Nonsense Mutation (SNP) | VAF 12/45 reads (27%) | catalogued as COSV58242918; called by muse, mutect2, varscan2
- NRP1 | c.320T>A p.I107K | Missense Mutation (SNP) | VAF 7/102 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV55161161; called by muse, mutect2
- PAPOLA | c.1930A>G p.T644A | Missense Mutation (SNP) | VAF 63/155 reads (41%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as COSV53479497; called by muse, mutect2, varscan2
- PAX4 | c.739C>A p.P247T | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.02); catalogued as rs990969828, COSV58387699; called by muse, mutect2, varscan2
- PCDHGB1 | c.2237A>C p.Y746S | Missense Mutation (SNP) | VAF 18/183 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV53908972; called by muse, mutect2, varscan2
- PCSK9 | c.271T>A p.S91T | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV56160861; called by muse, mutect2, varscan2
- PCSK9 | c.272C>T p.S91L | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV56160886; called by muse, mutect2, varscan2
- PKD1L1 | c.6128G>T p.G2043V | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV56959221, COSV56962854; called by muse, mutect2, varscan2
- PKN2 | c.565G>T p.V189F | Missense Mutation (SNP) | VAF 40/195 reads (21%) | SIFT tolerated (0.4); PolyPhen benign (0.033); catalogued as COSV60130246; called by muse, mutect2, varscan2
- PLA2G4D | c.175T>C p.F59L | Missense Mutation (SNP) | VAF 64/259 reads (25%) | SIFT tolerated (0.77); PolyPhen benign (0.003); catalogued as COSV51819505; called by muse, mutect2, varscan2
- PPIE | c.302G>T p.W101L | Missense Mutation (SNP) | VAF 17/94 reads (18%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.835); catalogued as COSV60970909; called by muse, mutect2, varscan2
- PPIP5K2 | c.2031C>G p.I677M | Missense Mutation (SNP) | VAF 53/195 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV58603179; called by muse, mutect2, varscan2
- PROCR | c.340T>A p.C114S | Missense Mutation (SNP) | VAF 25/142 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV53825330; called by muse, mutect2, varscan2
- RAB5IF | c.236C>T p.A79V | Missense Mutation (SNP) | VAF 81/345 reads (23%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.843); catalogued as COSV53410298; called by muse, varscan2
- RABAC1 | c.314G>A p.G105D | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV55770708; called by muse, mutect2, varscan2
- RASGRF2 | c.3305G>A p.R1102K | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.522); catalogued as COSV54123994, COSV54134192, COSV99430793; called by muse, mutect2, varscan2
- RBM7 | c.226T>C p.Y76H | Missense Mutation (SNP) | VAF 47/163 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.02); catalogued as COSV57784040; called by muse, mutect2, varscan2
- SH3GLB1 | c.695A>T p.E232V | Missense Mutation (SNP) | VAF 36/158 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); catalogued as COSV65279218; called by muse, mutect2, varscan2
- SPATA25 | c.283C>T p.H95Y | Missense Mutation (SNP) | VAF 68/300 reads (23%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as COSV51940872; called by muse, mutect2, varscan2
- SPTBN4 | c.5822C>G p.T1941R | Missense Mutation (SNP) | VAF 28/151 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV58944754; called by muse, mutect2, varscan2
- TECTB | c.497C>G p.S166C | Missense Mutation (SNP) | VAF 25/87 reads (29%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.557); catalogued as COSV65594811; called by muse, mutect2, varscan2
- TENM4 | c.8282T>C p.M2761T | Missense Mutation (SNP) | VAF 112/481 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.071); catalogued as COSV53612307; called by muse, mutect2, varscan2
- TRAPPC11 | c.2779A>G p.I927V | Missense Mutation (SNP) | VAF 22/102 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as rs896056101, COSV58215066; called by muse, mutect2, varscan2
- TSNAX | c.83A>T p.D28V | Missense Mutation (SNP) | VAF 9/197 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.035); catalogued as COSV64145865; called by muse, mutect2
- ZFR | c.2080C>G p.P694A | Missense Mutation (SNP) | VAF 33/151 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); catalogued as COSV54050829; called by muse, mutect2, varscan2
- ZPBP2 | c.796G>A p.V266M (on ENST00000348931 / NM_199321.3; = p.V244M on NM_198844.3) | Missense Mutation (SNP) | VAF 12/122 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.273); catalogued as COSV62375012; called by muse, mutect2, varscan2
- ZSCAN1 | c.61G>T p.E21* | Nonsense Mutation (SNP) | VAF 7/20 reads (35%) | catalogued as rs1313064562, COSV56602321; called by muse, varscan2
- AVL9 | c.228del p.H77Tfs*26 | Frame Shift Del (DEL) | VAF 19/78 reads (24%) | called by mutect2, pindel, varscan2
- CDK13 | c.1762dup p.T588Nfs*31 | Frame Shift Ins (INS) | VAF 10/103 reads (10%) | called by mutect2, pindel, varscan2
- GABRB1 | c.911_912del p.K304Sfs*3 | Frame Shift Del (DEL) | VAF 22/127 reads (17%) | called by mutect2, pindel, varscan2
- GATA2 | c.1052dup p.N351Kfs*33 | Frame Shift Ins (INS) | VAF 25/79 reads (32%) | called by mutect2, pindel, varscan2
- NBEAL1 | c.6489_6490del p.E2163Dfs*9 | Frame Shift Del (DEL) | VAF 24/86 reads (28%) | called by mutect2, pindel
- NOP2 | c.1315_1316dup p.H441Afs*36 (on ENST00000322166 / NM_001258308.2; = p.H437Afs*36 on NM_006170.4 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 7/31 reads (23%) | called by mutect2, pindel, varscan2
- PBRM1 | c.1343del p.L448Wfs*5 | Frame Shift Del (DEL) | VAF 12/50 reads (24%) | called by mutect2, pindel
- POLR1A | c.3842_3850dup p.L1281_K1283dup | In Frame Ins (INS) | VAF 50/346 reads (14%) | called by mutect2, varscan2
- UBR4 | c.14052_14073del p.Q4684Hfs*5 | Frame Shift Del (DEL) | VAF 34/138 reads (25%) | called by mutect2, pindel
- YIF1A | c.497_501del p.E166Afs*31 | Frame Shift Del (DEL) | VAF 17/60 reads (28%) | called by mutect2, pindel, varscan2
- ACSBG2 | c.948C>T p.V316= | Silent (SNP) | VAF 11/51 reads (22%) | catalogued as COSV53123199, COSV53125331; called by muse, mutect2, varscan2
- APBB2 | c.750C>T p.I250= | Silent (SNP) | VAF 153/618 reads (25%) | catalogued as COSV55948024; called by muse, mutect2, varscan2
- BAZ1A | c.1248G>T p.V416= | Silent (SNP) | VAF 35/133 reads (26%) | catalogued as COSV62409081, COSV62409237; called by muse, mutect2, varscan2
- C2CD3 | c.5643C>A p.S1881= | Silent (SNP) | VAF 21/81 reads (26%) | catalogued as COSV58090222; called by muse, mutect2, varscan2
- CD101 | c.2502C>T p.C834= | Silent (SNP) | VAF 27/116 reads (23%) | catalogued as rs754967595, COSV56716462; called by muse, mutect2, varscan2
- ESYT2 | c.2409T>A p.L803= (on ENST00000613624; = p.L727= on NM_020728.3) | Silent (SNP) | VAF 11/179 reads (6%) | catalogued as COSV51748250; called by muse, mutect2
- GAA | c.2268C>T p.L756= | Silent (SNP) | VAF 22/80 reads (28%) | catalogued as rs746873847, COSV56407230; called by mutect2, varscan2
- HDAC6 | c.1554C>T p.G518= | Silent (SNP) | VAF 21/47 reads (45%) | catalogued as COSV61927789; called by muse, mutect2, varscan2
- HHIP | c.1461T>C p.S487= | Silent (SNP) | VAF 25/94 reads (27%) | catalogued as COSV56837051; called by muse, mutect2, varscan2
- LAMC2 | c.162C>A p.L54= | Silent (SNP) | VAF 114/454 reads (25%) | catalogued as COSV51452946, COSV51454530; called by muse, mutect2, varscan2
- MMP2 | c.645G>A p.L215= | Silent (SNP) | VAF 15/95 reads (16%) | catalogued as COSV54599388; called by muse, mutect2, varscan2
- OR8D1 | c.153C>T p.V51= | Silent (SNP) | VAF 7/145 reads (5%) | catalogued as COSV63441756; called by muse, mutect2
- PATJ | c.534A>G p.R178= | Silent (SNP) | VAF 22/71 reads (31%) | catalogued as rs1450785845, COSV57156751; called by muse, mutect2, varscan2
- PHACTR4 | c.1227C>A p.P409= (on ENST00000373839 / NM_001350159.2; = p.P419= on NM_023923.4) | Silent (SNP) | VAF 37/103 reads (36%) | catalogued as COSV65783273; called by muse, mutect2, varscan2
- PLEC | c.4623G>C p.R1541= (on ENST00000322810 / NM_201380.4; = p.R1431= on NM_000445.5) | Silent (SNP) | VAF 14/28 reads (50%) | catalogued as COSV59609582; called by muse, mutect2, varscan2
- S100A7A | c.291T>C p.S97= | Silent (SNP) | VAF 18/75 reads (24%) | catalogued as rs368536104; called by muse, mutect2, varscan2
- SLC22A4 | c.384C>T p.V128= | Silent (SNP) | VAF 7/20 reads (35%) | catalogued as rs770458543, COSV52357019; called by muse, mutect2, varscan2
- SMARCAL1 | c.2601A>G p.T867= | Silent (SNP) | VAF 47/133 reads (35%) | catalogued as COSV61920079; called by muse, mutect2, varscan2
- TSPY1 | c.633C>T p.F211= | Silent (SNP) | VAF 51/289 reads (18%) | catalogued as COSV70474924; called by muse, mutect2, varscan2
- AIFM1 | c.249+1245C>T | Intron (SNP) | VAF 100/182 reads (55%) | catalogued as COSV54852881; called by muse, mutect2, varscan2
- RETSAT | c.-2T>A | 5'UTR (SNP) | VAF 29/114 reads (25%) | catalogued as COSV99805914; called by muse, varscan2
